Somatic mutation profile of tumor specimen TCGA-36-2542-01A (aliquot TCGA-36-2542-01A-01D-1526-09) from TCGA case TCGA-36-2542, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 60.0 years (21,902 days).
Specimen TCGA-36-2542-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4f53577-98fe-4282-9aaf-d1c988e942fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2542-10A (Blood Derived Normal), aliquot TCGA-36-2542-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee6310b0-2f58-47b7-862a-506c6917c291

The open-access MAF lists 85 somatic variants for this specimen: 66 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 17, Frame Shift Del 5, Splice Site 5, Nonsense Mutation 4, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FN1 | c.773G>A p.C258Y | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553658948, COSV60559847; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PEX10 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as rs61750434, CM981515; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 102/143 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ARAP3 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV53353141; called by muse, mutect2, varscan2
- BSG | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757777232, COSV61077872; called by muse, mutect2, varscan2
- CCDC80 | c.304G>C p.V102L | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV99245105; called by muse, mutect2
- CDK13 | c.2870G>C p.R957P | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.5); catalogued as COSV51704181, COSV51705638; called by muse, mutect2, varscan2
- CPT1B | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV56418192; called by muse, mutect2, varscan2
- DACT1 | c.2390C>T p.T797M | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs1333081053, COSV60022588; called by muse, mutect2, varscan2
- DCC | c.2455+2T>A p.X819_splice | Splice Site (SNP) | VAF 35/69 reads (51%) | catalogued as COSV59123076; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 110/152 reads (72%) | catalogued as rs782442161; called by mutect2, pindel, varscan2
- DRD2 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60761003; called by muse, mutect2, varscan2
- ELL3 | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55857623; called by muse, mutect2, varscan2
- GLT8D1 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56478232; called by muse, mutect2, varscan2
- GNA11 | c.874T>G p.F292V | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50024186; called by muse, mutect2, varscan2
- ITIH5 | c.2581C>A p.Q861K | Missense Mutation (SNP) | VAF 142/336 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53671297; called by muse, mutect2, varscan2
- KCNE4 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV56055047; called by muse, mutect2, varscan2
- KLHDC2 | c.784G>C p.G262R | Missense Mutation (SNP) | VAF 33/327 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100027089; called by muse, mutect2, varscan2
- KMT2C | c.3613A>T p.K1205* | Nonsense Mutation (SNP) | VAF 42/309 reads (14%) | catalogued as COSV51463861; called by muse, mutect2, varscan2
- LAMA2 | c.2666G>A p.C889Y | Missense Mutation (SNP) | VAF 178/292 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70352658; called by muse, mutect2, varscan2
- LRRC20 | c.530A>C p.E177A (on ENST00000355790 / NM_207119.3; = p.E121A on NM_018205.4) | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV62938912; called by muse, mutect2
- LTA | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV101403240; called by muse, mutect2
- MCAT | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51793306; called by muse, mutect2, varscan2
- MEAF6 | c.534G>T p.R178S (on ENST00000296214 / NM_001270875.3; = p.E188D on NM_022756.6) | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV99952806; called by muse, mutect2
- METTL2A | c.1084C>G p.R362G | Missense Mutation (SNP) | VAF 168/224 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61045517; called by muse, mutect2, varscan2
- MICAL2 | c.3349C>A p.P1117T | Missense Mutation (SNP) | VAF 167/455 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56323768; called by muse, mutect2, varscan2
- NDUFS1 | c.1776G>C p.K592N | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51913329, COSV99261268; called by muse, mutect2
- OPCML | c.992T>A p.L331H | Missense Mutation (SNP) | VAF 129/395 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.88); catalogued as COSV59440240; called by muse, mutect2, varscan2
- PKP3 | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV58989121; called by muse, mutect2, varscan2
- PMPCB | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 39/367 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50787191; called by muse, mutect2, varscan2
- POPDC2 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51742834; called by muse, mutect2, varscan2
- POTEA | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1468846188; called by muse, mutect2, varscan2
- PRODH2 | c.158G>C p.G53A | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); catalogued as COSV56561139; called by muse, mutect2, varscan2
- RCN3 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV54543255; called by muse, mutect2, varscan2
- RCOR1 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 71/115 reads (62%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV51770905; called by muse, mutect2, varscan2
- RGS1 | c.302G>C p.S101T | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV66506026; called by muse, mutect2, varscan2
- RIF1 | c.1469G>C p.G490A | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54621525; called by muse, mutect2, varscan2
- SALL4 | c.2472T>A p.S824R | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV53854844; called by muse, mutect2, varscan2
- SI | c.2910A>T p.K970N | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV52292030; called by muse, mutect2, varscan2
- SLC13A4 | c.1814T>A p.V605D | Missense Mutation (SNP) | VAF 124/414 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.405); catalogued as COSV62462344; called by muse, varscan2
- SLC36A1 | c.420-1G>C p.X140_splice | Splice Site (SNP) | VAF 73/238 reads (31%) | catalogued as COSV54654186; called by muse, mutect2, varscan2
- SLC8A3 | c.1422T>G p.F474L | Missense Mutation (SNP) | VAF 100/156 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63524876; called by muse, mutect2, varscan2
- SNX14 | c.311G>C p.C104S | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59014782; called by muse, mutect2, varscan2
- SRD5A1 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 135/362 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs374499334; called by muse, mutect2, varscan2
- STX10 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52848602; called by mutect2, varscan2
- SYNJ1 | c.3236C>T p.T1079I | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs930892912, COSV59153453; called by muse, mutect2, varscan2
- SYT14 | c.1243T>G p.S415A | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs1327700640, COSV55060570; called by muse, mutect2, varscan2
- TAPBP | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.118); catalogued as COSV56471640; called by muse, mutect2, varscan2
- TGFB2 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.106); catalogued as COSV65110394; called by muse, mutect2, varscan2
- TH | c.860C>A p.A287D (on ENST00000381178 / NM_199292.3; = p.A256D on NM_000360.4) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV60768298; called by muse, mutect2, varscan2
- TMOD1 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 194/364 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs981892317, COSV52251150; called by muse, mutect2, varscan2
- TRIM55 | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99397085; called by muse, mutect2
- TRRAP | c.8102A>G p.N2701S (on ENST00000359863 / NM_001244580.1; = p.N2683S on NM_003496.3) | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.598); catalogued as rs755078580, COSV62851110; called by muse, mutect2, varscan2
- TSPYL2 | c.1619G>A p.G540D | Missense Mutation (SNP) | VAF 109/340 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.998); catalogued as COSV64920898; called by muse, mutect2, varscan2
- UPF3B | c.967A>T p.K323* (on ENST00000276201 / NM_080632.3; = p.K310* on NM_023010.3) | Nonsense Mutation (SNP) | VAF 37/358 reads (10%) | catalogued as COSV52230989, COSV52231649; called by muse, mutect2, varscan2
- USP7 | c.2827G>C p.E943Q | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV61216500; called by muse, mutect2, varscan2
- ZNF585A | c.278G>A p.R93H (on ENST00000292841 / NM_001288800.2; = p.R38H on NM_152655.3) | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs374585649; called by muse, mutect2, varscan2
- ZNF80 | c.488G>A p.C163Y | Missense Mutation (SNP) | VAF 125/256 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100352201, COSV57362103; called by muse, mutect2, varscan2
- ACSM2B | c.1025_1037del p.L342Rfs*23 | Frame Shift Del (DEL) | VAF 84/285 reads (29%) | called by mutect2, pindel, varscan2
- BRCA1 | c.3803_3815del p.N1268Tfs*3 | Frame Shift Del (DEL) | VAF 49/114 reads (43%) | called by mutect2, pindel, varscan2
- DCLRE1C | c.780+1_780+13del p.X260_splice (on ENST00000378278 / NM_001350965.2; = p.X145_splice on NM_022487.4) | Splice Site (DEL) | VAF 173/558 reads (31%) | called by mutect2, pindel, varscan2
- DOCK2 | c.524del p.P175Lfs*53 | Frame Shift Del (DEL) | VAF 69/259 reads (27%) | called by mutect2, pindel, varscan2
- PCGF2 | c.774_795del p.V259Lfs*53 | Frame Shift Del (DEL) | VAF 28/53 reads (53%) | called by mutect2, pindel, varscan2
- PLIN1 | c.734_771+13del p.X245_splice | Splice Site (DEL) | VAF 12/128 reads (9%) | called by mutect2, pindel
- RALGAPB | c.2743_2748del p.P916_S917del | In Frame Del (DEL) | VAF 14/139 reads (10%) | called by mutect2, pindel
- RASA1 | c.2740_2758+1del | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | called by mutect2, pindel, varscan2
- C3AR1 | c.1119C>T p.S373= | Silent (SNP) | VAF 95/300 reads (32%) | catalogued as rs777724881, COSV50818313, COSV50821795; called by muse, mutect2, varscan2
- GFAP | c.990G>A p.R330= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV53652410, COSV99493021; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1695T>A p.P565= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV61171811; called by muse, mutect2, varscan2
- MERTK | c.939G>A p.P313= | Silent (SNP) | VAF 39/563 reads (7%) | catalogued as rs747537140, COSV99775027; called by muse, mutect2
- MMUT | c.153G>T p.L51= | Silent (SNP) | VAF 95/377 reads (25%) | catalogued as COSV51278699; called by muse, mutect2, varscan2
- N4BP2 | c.4929T>A p.A1643= | Silent (SNP) | VAF 22/179 reads (12%) | catalogued as COSV54705158; called by muse, mutect2, varscan2
- OR6S1 | c.222G>A p.L74= | Silent (SNP) | VAF 77/192 reads (40%) | catalogued as COSV57838873; called by muse, mutect2, varscan2
- PARP12 | c.2052G>C p.S684= | Silent (SNP) | VAF 233/576 reads (40%) | catalogued as COSV54936232; called by muse, mutect2, varscan2
- PRKD2 | c.297C>T p.D99= | Silent (SNP) | VAF 68/141 reads (48%) | catalogued as COSV52184630, COSV52188736; called by muse, mutect2, varscan2
- PRPF6 | c.429A>C p.S143= | Silent (SNP) | VAF 122/211 reads (58%) | catalogued as COSV53875729; called by muse, mutect2, varscan2
- PTCHD1 | c.2427G>C p.L809= | Silent (SNP) | VAF 95/231 reads (41%) | catalogued as COSV65058940, COSV65060265, COSV65062032; called by muse, mutect2, varscan2
- RFT1 | c.577C>T p.L193= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs35728451, COSV99965551; called by muse, mutect2, varscan2
- SIM2 | c.81C>A p.L27= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as rs202090892, COSV51771481; called by muse, varscan2
- SLC5A11 | c.1923C>G p.A641= | Silent (SNP) | VAF 105/280 reads (38%) | catalogued as COSV61742989; called by muse, mutect2, varscan2
- TRIM55 | c.579G>T p.L193= | Silent (SNP) | VAF 28/294 reads (10%) | catalogued as COSV52550161, COSV99397088; called by muse, mutect2
- WDR26 | c.1110A>G p.E370= (on ENST00000414423 / NM_001379403.1; = p.E270= on NM_025160.7) | Silent (SNP) | VAF 21/202 reads (10%) | catalogued as COSV99691420; called by muse, mutect2, varscan2
- ZBED9 | c.1440A>T p.R480= | Silent (SNP) | VAF 55/119 reads (46%) | catalogued as COSV71729666; called by muse, mutect2, varscan2
- AP003393.1 | n.514+837G>C | Intron (SNP) | VAF 6/125 reads (5%) | catalogued as COSV100405678; called by muse, mutect2
- PGAP2 | c.165+5949C>A | Intron (SNP) | VAF 65/233 reads (28%) | catalogued as COSV53466555; called by muse, mutect2, varscan2
